Somatic mutation profile of tumor specimen TARGET-10-PARGMW-09A (aliquot TARGET-10-PARGMW-09A-01D) from TARGET case TARGET-10-PARGMW, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (923 days).
Specimen TARGET-10-PARGMW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 859c0c69-9c30-43ff-b25d-f448c704efc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARGMW-10A (Blood Derived Normal), aliquot TARGET-10-PARGMW-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d26e30f-cb84-4545-9701-b11c9ba0d1aa

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, Intron 2, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.359T>A p.V120D | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100875734; called by muse, mutect2, varscan2
- CCT8 | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | catalogued as COSV54503784; called by muse, mutect2
- DOCK1 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs557378130; called by muse, mutect2, varscan2
- EOGT | c.516-1G>T p.X172_splice | Splice Site (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- METTL7A | c.431C>A p.T144N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- OR6Q1 | c.823A>C p.N275H | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PRKAR2A | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PRPF19 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- RB1CC1 | c.1222G>T p.V408L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- SPATA31A6 | c.3724T>A p.F1242I | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.029); called by muse, mutect2
- BTBD2 | c.417G>T p.L139= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- COL6A2 | c.2082C>T p.L694= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs763384399; called by muse, mutect2
- EXOC1 | c.252C>A p.I84= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV62119772; called by muse, mutect2
- NRG1 | c.657A>C p.A219= | Silent (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- RCC2 | c.741G>T p.A247= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV64905933; called by muse, varscan2
- BBIP1 | c.38-6107G>T | Intron (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- EIF3IP1 | n.253C>T | RNA (SNP) | VAF 52/113 reads (46%) | catalogued as rs1425395134; called by muse, mutect2, varscan2
- ELP2 | c.523+573C>A | Intron (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100626861; called by muse, mutect2
